Somatic mutation profile of tumor specimen TCGA-DX-A23Y-01A (aliquot TCGA-DX-A23Y-01A-11D-A27P-09) from TCGA case TCGA-DX-A23Y, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 80.1 years (29,272 days).
Specimen TCGA-DX-A23Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e16ed365-1ccf-49e1-ada2-ade56702c9eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A23Y-10A (Blood Derived Normal), aliquot TCGA-DX-A23Y-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3a0b69b-2001-4bd3-9b0a-2c440f6d814f

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, Intron 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP1 | c.2432+1G>T p.X811_splice | Splice Site (SNP) | VAF 3/43 reads (7%) | catalogued as COSV100532564; called by muse, mutect2
- CCDC134 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs369237416; called by muse, mutect2, varscan2
- DNAI2 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs769115235, COSV100209509; called by muse, mutect2, varscan2
- GKAP1 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as rs554092166, COSV64487280; called by muse, mutect2, varscan2
- HNRNPA1 | c.628T>A p.F210I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV99267302; called by muse, mutect2, varscan2
- HSP90AB1 | c.403T>G p.S135A | Missense Mutation (SNP) | VAF 30/409 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100806881; called by muse, mutect2
- MAGI1 | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100438947; called by muse, mutect2, varscan2
- MC2R | c.131T>A p.I44N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV100562845; called by muse, mutect2
- MUC5AC | c.14567T>C p.V4856A | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.757); catalogued as rs1316990313, COSV100611269; called by muse, mutect2, varscan2
- NLRP4 | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100015407; called by muse, mutect2, varscan2
- NWD1 | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.051); catalogued as COSV100341528; called by muse, mutect2, varscan2
- OR2M4 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100140915; called by muse, mutect2, varscan2
- OR2T12 | c.942T>G p.N314K | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100527474; called by muse, mutect2, varscan2
- PRB2 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV101231358, COSV104430975; called by muse, mutect2, varscan2
- PREP | c.208G>A p.G70S (on ENST00000369110; = p.G136S on NM_002726.5) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100963652; called by muse, mutect2, varscan2
- PRRC2C | c.8092A>C p.N2698H (on ENST00000367742; = p.N2696H on NM_015172.4) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100144517; called by muse, mutect2, varscan2
- RALGPS1 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.439); catalogued as COSV99400547; called by muse, mutect2, varscan2
- RERE | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (1); catalogued as rs1237959147, COSV100555114; called by muse, mutect2, varscan2
- REV3L | c.6620G>C p.R2207T | Missense Mutation (SNP) | VAF 394/476 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV100724731, COSV62615472; called by muse, mutect2, varscan2
- RNF213 | c.1715A>T p.Q572L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as COSV100172863; called by muse, mutect2, varscan2
- SLC25A35 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs772697507, COSV99873632; called by muse, mutect2, varscan2
- SMTN | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV60779731; called by muse, mutect2, varscan2
- SPRY3 | c.33A>T p.Q11H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as COSV100249111; called by muse, mutect2, varscan2
- TBC1D4 | c.3716C>T p.T1239M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs375003443; called by muse, mutect2, varscan2
- THAP12 | c.1265T>C p.I422T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV99472713; called by muse, mutect2, varscan2
- TMEM132D | c.3143C>A p.T1048N | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV101242512; called by muse, mutect2, varscan2
- TMPRSS3 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as rs976363536, CM1111510, COSV99367498; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1727A>C p.D576A | Missense Mutation (SNP) | VAF 118/467 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99690953; called by muse, mutect2, varscan2
- ADGRG1 | c.1269C>T p.A423= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as rs768984787, COSV101113302; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- AEBP1 | c.3039C>T p.P1013= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs1344623643, COSV99788287; called by muse, mutect2, varscan2
- AMZ1 | c.150G>A p.P50= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs774728197, COSV56688763; called by muse, mutect2, varscan2
- BMP1 | c.2295C>T p.D765= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100114451; called by muse, mutect2, varscan2
- GALNTL6 | c.876C>A p.I292= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV101560007; called by muse, mutect2, varscan2
- HCAR3 | c.543C>T p.S181= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as rs777311419, COSV100811408, COSV63673422; called by muse, mutect2, varscan2
- HMMR | c.2139C>T p.Y713= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as rs1453745826, COSV100700952; called by muse, mutect2
- MUC17 | c.3417T>C p.S1139= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV100071168; called by muse, mutect2, varscan2
- TMEM63B | c.2343G>A p.V781= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as COSV52479313; called by muse, mutect2, varscan2
- UTP20 | c.2967G>A p.V989= | Silent (SNP) | VAF 158/258 reads (61%) | catalogued as COSV99880567; called by muse, mutect2, varscan2
- UTP20 | c.3615G>A p.L1205= | Silent (SNP) | VAF 105/170 reads (62%) | catalogued as COSV99880569; called by muse, mutect2, varscan2
- ZBTB46 | c.1278G>A p.S426= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV99828642; called by muse, mutect2, varscan2
- MAST4 | c.675-49386del | Intron (DEL) | VAF 13/61 reads (21%) | called by mutect2, varscan2
